Gene-level copy-number profile of tumor specimen TCGA-KN-8425-01A from TCGA case TCGA-KN-8425, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 53.9 years (19,692 days).
Specimen TCGA-KN-8425-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KICH.c9c2f1c9-f7fc-4b5b-a48c-59f09bb69b7f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KN-8425-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2f1cd32d-06a5-49f1-b389-4565114413d1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 2: 25,797; copy number 3: 13,644; copy number 4: 20,377.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KN-8425-01A-11D-2308-01): tumor purity 0.66, ploidy 2.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,994,618–88,049,823, 2 genes: AC063965.1, MED6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
